Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2OV, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2OV-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

Patient

Name:

MRN:

DOB:

Gender: F

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Ordering

MD:

Copy To:

Reviewed Initial	8/31/11	8/18/11

Specimen(s) Received

1. Thyroid: subtotal thyroidectomy; stitch marks upper pole left side

Diagnosis

Multifocal papillary carcinoma, dominant oncocytic follicular variant, 2.1 cm; follicular adenoma with degeneration, follicular nodular disease with degeneration and reactive atypia:
Thyroid

No pathological diagnosis: Lymph node, isthmus
- Left hemithyroidectomy specimen

ICD-0-3

Carcinoma, papillary, follicular variant

Synoptic Data

Procedure: Left hemithyroidectomy
Received: Fresh
Specimen Integrity: Intact
Specimen Size: Left lobe:
7.6 cm
4.4 cm
3.1 cm
Isthmus +/- pyramidal lobe:
4.1 cm
2.5 cm
1.9 cm
Specimen Weight: 65.2 g
Tumor Focality: Multifocal

Site: Thyroid, NOS 8340/3
C73.9
8/31/11

----- DOMINANT TUMOR -----

Tumor Laterality: Left lobe
Tumor Size: Greatest dimension: 2.1 cm
Additional dimension: 1.5 cm

Histologic Type: Papillary carcinoma, follicular variant Per TSS, follicular variant = 100%
Papillary carcinoma, oncocytic or oxyphilic variant

[page 2 of 3]
	Follicular architecture
	Oncocytic or oxyphilic cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Totally encapsulated
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
----- SECOND TUMOR -----	
Tumor Laterality:	Isthmus
Tumor Size:	Greatest dimension: 0.1 cm
Histologic Type:	Papillary carcinoma, follicular variant
	Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant
	Follicular architecture
	Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	None
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis
	Number of regional lymph nodes examined: 1
	Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Adenoma
	Adenomatoid nodule(s) or Nodular follicular disease
	Thyroiditis, focal (nonspecific)

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically

verified by:

Clinical History

Left thyroid mass

Gross Description

The specimen labeled with the patient's name and as "Subtotal thyroidectomy; stitch marks upper pole left side", consists of a left hemithyroidectomy specimen that weighs 65.2 g. The lobe measures 7.6 cm SI x 4.4 cm ML x 3.1 cm AP and the isthmus measures 4.1 SI x 1.9 cm ML x 2.5 cm AP. No parathyroid glands or lymph nodes are identified grossly. The isthmus and left lobe contain multiple delineated nodules that measure from 0.5 to 2.5 cm in maximum dimension. Several of the large nodules demonstrate partial calcification of the capsule. Very little grossly normal thyroid tissue is identified. Sections of nodule and normal tissue are stored frozen. Representative sections of the remainder of the specimen are submitted as follows:

[page 3 of 3]
1A-H lobe, superior to inferior
1I-L isthmus

Source: NCI Genomic Data Commons file f9b5344c-eaa9-485c-bc5f-e783505f6ec7 (TCGA-EM-A2OV.AE90D1AA-219B-49A9-8BF5-864EB67A572D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).